Somatic mutation profile of tumor specimen BA2775D (aliquot aq-BA2775D) from BEATAML1.0 case 2138, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 27.0 years (9,857 days).
Specimen BA2775D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0f38372-8510-4f16-a8f0-209c6711ab6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2396D (Solid Tissue Normal), aliquot aq-BA2396D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/774844a8-53fb-4be5-ad7e-6d1029ba680c

The open-access MAF lists 15 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 3, In Frame Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 95/212 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R4 | c.3481A>G p.S1161G | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1476315417; called by muse, mutect2, varscan2
- RFC4 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56218335; called by muse, mutect2, varscan2
- SOGA1 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.724); catalogued as rs1396229230, COSV52931275; called by muse, mutect2, varscan2
- CBL | c.1091_1095+4del | In Frame Del (DEL) | VAF 26/171 reads (15%) | called by mutect2, pindel, varscan2
- HOXB5 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2
- WDR47 | c.2732C>T p.T911I (on ENST00000369962 / NM_001142551.2; = p.T912I on NM_014969.5) | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXRED1 | c.954T>C p.P318= | Silent (SNP) | VAF 57/160 reads (36%) | called by muse, mutect2, varscan2
- MYCT1 | c.153T>C p.N51= | Silent (SNP) | VAF 52/114 reads (46%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1926G>A p.V642= | Silent (SNP) | VAF 71/296 reads (24%) | catalogued as rs782339275; called by muse, mutect2, varscan2
- CDK16 | c.-196G>A | 5'UTR (SNP) | VAF 6/49 reads (12%) | catalogued as rs1556796314; called by muse, mutect2
- CPNE3 | c.1069-15G>A | Intron (SNP) | VAF 61/140 reads (44%) | called by muse, mutect2, varscan2
- MAPKBP1 | c.328-227C>A | Intron (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- NPIPB1P | n.238C>T | RNA (SNP) | VAF 93/196 reads (47%) | called by muse, mutect2, varscan2
- PRRG3 | c.168+11C>A | Intron (SNP) | VAF 66/76 reads (87%) | called by muse, mutect2, varscan2
